Somatic mutation profile of tumor specimen 0DRB5M from CCDI case PBCGCC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.8 years (4,685 days).
Specimen 0DRB5M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54c04b63-7f48-4756-bf5f-7b9e1332eea1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRB5X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d99eec62-1ad5-4b60-9b03-991dbf8c2d8c

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Frame Shift Del 3, Missense Mutation 3, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPERD | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 215/552 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1416219966; called by muse, mutect2, varscan2
- MKI67 | c.8775_8776del p.Q2926Nfs*6 | Frame Shift Del (DEL) | VAF 338/1041 reads (32%) | catalogued as rs1173089014; called by pindel, varscan2
- OTUB1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 134/321 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99734772; called by muse, mutect2, varscan2
- POLR1A | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 180/411 reads (44%) | catalogued as rs772459266; called by muse, mutect2, varscan2
- TTN | c.76723C>T p.R25575C (on ENST00000591111; = p.R18151C on NM_003319.4) | Missense Mutation (SNP) | VAF 393/910 reads (43%) | PolyPhen probably damaging (0.998); catalogued as rs756815015, COSV59899329; called by muse, mutect2, varscan2
- AHDC1 | c.1462del p.R488Gfs*11 | Frame Shift Del (DEL) | VAF 147/486 reads (30%) | called by mutect2, pindel, varscan2
- OBSCN | c.17090_17091del p.V5697Dfs*8 | Frame Shift Del (DEL) | VAF 140/379 reads (37%) | called by pindel, varscan2
- CACTIN | c.1395G>A p.L465= | Silent (SNP) | VAF 93/289 reads (32%) | catalogued as rs759318520; called by muse, mutect2, varscan2
- GPR148 | c.597T>C p.A199= | Silent (SNP) | VAF 302/706 reads (43%) | catalogued as rs751744051; called by muse, mutect2, varscan2
- OR2A4 | c.51C>T p.P17= | Silent (SNP) | VAF 183/527 reads (35%) | catalogued as rs1399240639, COSV100199643; called by muse, mutect2, varscan2
- TGFA | c.267C>T p.A89= | Silent (SNP) | VAF 350/826 reads (42%) | catalogued as rs782179034; called by muse, mutect2, varscan2
- USP38 | c.1120T>C p.L374= | Silent (SNP) | VAF 324/790 reads (41%) | called by muse, mutect2, varscan2
- UTP20 | c.7911G>A p.S2637= | Silent (SNP) | VAF 280/668 reads (42%) | catalogued as rs150556992; called by muse, mutect2, varscan2
- CXCR3 | c.13-16G>A | Intron (SNP) | VAF 247/583 reads (42%) | catalogued as rs764708198, COSV65461906; called by muse, mutect2, varscan2
- FAM20C | c.1445+14C>T | Intron (SNP) | VAF 164/422 reads (39%) | catalogued as rs550809892; called by muse, mutect2, varscan2
- PPBP | c.*77A>C | 3'UTR (SNP) | VAF 108/266 reads (41%) | called by muse, mutect2, varscan2
